Somatic mutation profile of tumor specimen 0DTLGJ from CCDI case PBCJSE, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.6 years (2,055 days).
Specimen 0DTLGJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b3fad344-c2f2-44ed-8ea6-2602d28daae9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTLGE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/795688f8-9eb0-4f63-9d94-f56e7d0bd6a9

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 3, Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL9A3 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 360/801 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as rs145729725; called by muse, mutect2, varscan2
- ITGB3 | c.2071G>A p.V691I | Missense Mutation (SNP) | VAF 645/1936 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.012); catalogued as rs534325095, COSV71383530; called by muse, mutect2, varscan2
- LIMK2 | c.915C>G p.F305L | Missense Mutation (SNP) | VAF 40/1474 reads (3%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100058466; called by muse, mutect2
- MGAT4C | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 467/1179 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF222 | c.461T>A p.F154Y | Missense Mutation (SNP) | VAF 36/1256 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2
- GABRA2 | c.378C>A p.T126= | Silent (SNP) | VAF 600/1514 reads (40%) | called by muse, mutect2
- FGG | c.308-38T>G | Intron (SNP) | VAF 466/938 reads (50%) | called by muse, mutect2, varscan2
- GFPT2 | c.677-62G>C | Intron (SNP) | VAF 29/286 reads (10%) | called by muse, mutect2
- OR11H2 | chr14:19713921 A>C | 5'Flank (SNP) | VAF 98/381 reads (26%) | catalogued as rs769918320; called by muse, mutect2, varscan2
- RCOR1 | c.1054-61C>A | Intron (SNP) | VAF 107/199 reads (54%) | catalogued as rs949030815; called by muse, mutect2, varscan2
